Somatic mutation profile of tumor specimen TCGA-AG-3896-01A (aliquot TCGA-AG-3896-01A-01W-1073-09) from TCGA case TCGA-AG-3896, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 85.0 years (31,046 days).
Specimen TCGA-AG-3896-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53d4b36e-d80d-49ec-9b95-acad2e9f2b86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3896-10A (Blood Derived Normal), aliquot TCGA-AG-3896-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78facf5e-6b49-4ffc-a3ae-8b9a37464097

The open-access MAF lists 127 somatic variants for this specimen: 99 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 26, Nonsense Mutation 6, Splice Site 3, Frame Shift Ins 1, Intron 1, RNA 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 105/169 reads (62%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HMGCL | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs121964997, CM980987, COSV52525123, COSV99354186; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs118192211, CM073161, CM135153, COSV60431884, COSV60431891; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.1957-2A>G p.X653_splice (on ENST00000272895 / NM_173076.3; = p.X335_splice on NM_015657.3) | Splice Site (SNP) | VAF 28/304 reads (9%) | catalogued as COSV99792370; called by muse, mutect2
- ACTL9 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61004787; called by muse, mutect2, varscan2
- ADGRB3 | c.3836G>T p.R1279I | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV53235028; called by muse, mutect2, varscan2
- ADGRG6 | c.287A>C p.Y96S | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51586814; called by muse, mutect2, varscan2
- AMER1 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 40/68 reads (59%) | catalogued as rs1408150272, COSV57655083; called by muse, mutect2, varscan2
- AR | c.2482T>C p.F828L | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as CM014507, CM153979, COSV65953196; called by muse, mutect2, varscan2
- ARHGEF10L | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs747683250, COSV51428138; called by muse, mutect2, varscan2
- CACNA1S | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1800559, CM970210, COSV62936287; ClinVar: risk factor; called by muse, mutect2, varscan2
- CMYA5 | c.4716G>T p.E1572D | Missense Mutation (SNP) | VAF 24/855 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV101484432; called by muse, mutect2
- COL4A5 | c.4548G>C p.M1516I | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60356287, COSV60363008; called by muse, mutect2, varscan2
- CORIN | c.3071C>T p.S1024L | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs868207934, COSV56686345; called by muse, mutect2, varscan2
- CYB5R4 | c.741dup p.E248Rfs*16 | Frame Shift Ins (INS) | VAF 62/280 reads (22%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP11B1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as rs200867786, COSV52824880, COSV52825943; called by muse, mutect2, varscan2
- DCLK3 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 98/414 reads (24%) | catalogued as COSV69362220; called by muse, mutect2, varscan2
- DHRS7C | c.569C>T p.T190M (on ENST00000330255 / NM_001220493.2; = p.T189M on NM_001105571.3) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs374278019; called by muse, mutect2, varscan2
- DIS3 | c.954_956del p.E318del | In Frame Del (DEL) | VAF 28/274 reads (10%) | catalogued as rs745919298; called by pindel, varscan2
- EML4 | c.2680C>A p.Q894K | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.031); catalogued as COSV100581474; called by muse, mutect2
- FAM47A | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 109/198 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.248); catalogued as COSV60494063; called by muse, mutect2, varscan2
- FAT4 | c.10087C>G p.L3363V | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58671994, COSV58678908; called by muse, mutect2
- GIGYF2 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 288/827 reads (35%) | catalogued as COSV65246625; called by muse, mutect2, varscan2
- GMEB1 | c.1124A>T p.K375M | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53792914; called by muse, mutect2, varscan2
- GMEB2 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56605723; called by muse, mutect2
- GUCY2F | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV99485794; called by muse, mutect2
- ITIH6 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs746683216, COSV54486547; called by muse, varscan2
- KCNJ1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1175132953, COSV60661282; called by muse, mutect2, varscan2
- KCNS2 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54637276; called by muse, mutect2, varscan2
- KRT6A | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs767267061, COSV58103704; called by muse, mutect2, varscan2
- KRTAP10-9 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as rs587668632, COSV59952037; called by muse, mutect2, varscan2
- LAMA2 | c.1781A>G p.K594R | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs1369278967, COSV101370909; called by muse, mutect2
- LRRC17 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV99978727; called by muse, mutect2
- LRRIQ3 | c.1533G>C p.K511N | Missense Mutation (SNP) | VAF 32/683 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100599558; called by muse, mutect2
- LUC7L2 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as rs774057231, COSV54923602; called by muse, mutect2, varscan2
- MITF | c.591G>C p.K197N (on ENST00000448226 / NM_006722.3; = p.K91N on NM_000248.4) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.634); catalogued as COSV58829946; called by muse, mutect2, varscan2
- MMS22L | c.2129T>A p.L710H | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99247862; called by muse, mutect2
- MOGS | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs771226355, COSV51968152; called by muse, mutect2, varscan2
- MUC16 | c.37531G>A p.V12511M | Missense Mutation (SNP) | VAF 454/1052 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.266); catalogued as rs375258130; called by muse, mutect2, varscan2
- MYLK3 | c.893T>C p.L298S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67362589; called by muse, mutect2, varscan2
- MYO9A | c.6629C>T p.A2210V | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100614523; called by muse, mutect2
- N4BP2 | c.2366G>C p.G789A | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99789361; called by muse, mutect2
- NAA25 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 100/478 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV55702102; called by muse, mutect2, varscan2
- NFYA | c.635C>G p.T212R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV58197850; called by muse, mutect2, varscan2
- NOTCH4 | c.1451G>A p.C484Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66678792; called by muse, mutect2, varscan2
- NPPB | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs143526178, COSV64687549; called by muse, mutect2, varscan2
- OR5H6 | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 21/413 reads (5%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV101051825; called by muse, mutect2
- PASD1 | c.2161C>G p.P721A | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64854128; called by muse, mutect2
- PCDHA1 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1167626504, COSV65372718; called by muse, mutect2, varscan2
- PDE10A | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as rs1403420962, COSV63091276; called by muse, mutect2, varscan2
- PI4KA | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs779385030, COSV55404206; called by muse, mutect2, varscan2
- PITRM1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs770738350, COSV56526098; called by muse, mutect2, varscan2
- PLXNC1 | c.4602+2T>G p.X1534_splice | Splice Site (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99314015; called by muse, mutect2, varscan2
- POGZ | c.1700G>A p.W567* | Nonsense Mutation (SNP) | VAF 42/174 reads (24%) | catalogued as COSV55032332; called by muse, mutect2, varscan2
- PPRC1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as rs1291063195, COSV53383146; called by muse, mutect2, varscan2
- PRKAG2 | c.1007T>C p.V336A | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as CM166719, COSV99836236; called by muse, mutect2
- PUS7 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.336); catalogued as rs761478623, COSV62675894; called by muse, mutect2, varscan2
- RAD17 | c.570G>T p.Q190H (on ENST00000380774 / NM_133339.2; = p.Q179H on NM_002873.1) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs1189560056, COSV51456116; called by muse, mutect2, varscan2
- RAD21 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV52056252; called by muse, mutect2, varscan2
- RASSF9 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 90/366 reads (25%) | catalogued as rs1053694318, COSV63432565; called by muse, mutect2, varscan2
- RBCK1 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV62291662; called by muse, varscan2
- RFX3 | c.1972G>A p.G658S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV65858301; called by muse, mutect2, varscan2
- RGS7BP | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 82/123 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV61833511; called by muse, mutect2, varscan2
- RNF148 | c.35G>A p.S12N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57349888; called by muse, mutect2, varscan2
- RSPO2 | c.549C>A p.D183E | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); catalogued as COSV52638603; called by muse, mutect2, varscan2
- SCN9A | c.5034G>C p.M1678I (on ENST00000303354; = p.M1667I on NM_002977.3) | Missense Mutation (SNP) | VAF 42/618 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.29); catalogued as COSV100314461; called by muse, mutect2
- SGCB | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs754884547, COSV67340541; called by muse, mutect2, varscan2
- SIGLECL1 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 161/593 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV57062041; called by muse, mutect2, varscan2
- SLC30A1 | c.934T>A p.W312R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183933041, COSV65360512; called by muse, mutect2, varscan2
- SLC43A3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201915801, COSV61449811; called by muse, mutect2, varscan2
- SLC8A1 | c.1931A>T p.E644V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV100247604; called by muse, mutect2
- SMAD2 | c.997+1G>A p.X333_splice | Splice Site (SNP) | VAF 32/63 reads (51%) | catalogued as rs367537999, CS135220, COSV100054141; ClinVar: not provided; called by muse, mutect2, varscan2
- SMAD3 | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59280651, COSV59289178; called by muse, mutect2, varscan2
- SORL1 | c.698A>T p.K233M | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.786); catalogued as COSV52749513; called by muse, mutect2, varscan2
- SPTA1 | c.6921G>T p.L2307F | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63748987; called by muse, mutect2
- TAGAP | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs751645528, COSV57850520; called by muse, mutect2, varscan2
- TCTE1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs112092930, COSV65255064; called by muse, mutect2, varscan2
- TLE2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.074); catalogued as rs1459896300, COSV99504747; called by muse, mutect2, varscan2
- TMC3 | c.2801G>A p.R934H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1028770773, COSV63922102; called by muse, mutect2, varscan2
- TMEM214 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53191817; called by muse, varscan2
- TNFSF4 | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99919546; called by muse, mutect2
- TRPM4 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53260289; called by muse, mutect2, varscan2
- TSGA10 | c.1649T>C p.I550T | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV61822060; called by muse, mutect2, varscan2
- TSHZ2 | c.932C>A p.T311N | Missense Mutation (SNP) | VAF 14/430 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV100296876; called by muse, mutect2
- UNC13C | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs536918048, COSV52844678; called by muse, mutect2, varscan2
- USH2A | c.7903G>A p.D2635N | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56329020; called by muse, mutect2, varscan2
- VRK2 | c.1516T>G p.F506V | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52072689; called by muse, mutect2, varscan2
- XKR5 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs965780263; called by muse, mutect2, varscan2
- ZC3H12B | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100162140; called by muse, mutect2
- ZFHX4 | c.6692C>T p.T2231M | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50500300; called by muse, mutect2, varscan2
- ZNF117 | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV51426190; called by muse, mutect2, varscan2
- ZNF230 | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 100/423 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.15); catalogued as rs1161993475, COSV71273233; called by muse, mutect2, varscan2
- ZNF280B | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 18/465 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV100840467; called by muse, mutect2
- ZNF468 | c.818G>T p.C273F | Missense Mutation (SNP) | VAF 27/460 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99700891; called by muse, mutect2
- ZNF518A | c.3759A>C p.K1253N | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100283608, COSV60150226; called by muse, mutect2, varscan2
- ZNF804B | c.2368T>A p.S790T | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as COSV60816653; called by muse, mutect2, varscan2
- PPFIA2 | c.2324_2325insCCC p.P777dup | In Frame Ins (INS) | VAF 54/163 reads (33%) | called by mutect2, pindel, varscan2
- ATP6V0A2 | c.2220C>T p.I740= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs770098416, COSV57747761, COSV57751915; called by muse, mutect2, varscan2
- BNC2 | c.2943C>T p.D981= | Silent (SNP) | VAF 75/133 reads (56%) | catalogued as rs374901966; called by muse, mutect2, varscan2
- CSMD3 | c.4164C>T p.H1388= (on ENST00000297405 / NM_001363185.1; = p.H1284= on NM_052900.3) | Silent (SNP) | VAF 80/158 reads (51%) | catalogued as rs140111920; called by muse, mutect2, varscan2
- DUOX1 | c.4179C>T p.T1393= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs768386196, COSV52049362; called by muse, mutect2, varscan2
- FAM153B | c.141C>T p.P47= | Silent (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- FGF6 | c.186C>T p.R62= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs202212518, COSV57403376; called by muse, mutect2, varscan2
- FILIP1 | c.2196C>T p.H732= | Silent (SNP) | VAF 328/687 reads (48%) | catalogued as rs754618124, COSV52723104; called by muse, mutect2, varscan2
- FLG | c.7611T>A p.A2537= | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as COSV64236649; called by muse, mutect2
- H1-5 | c.291G>A p.V97= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as COSV58899036; called by muse, mutect2, varscan2
- KIAA1958 | c.1914C>T p.Y638= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV61721671; called by muse, mutect2, varscan2
- LUZP4 | c.762C>T p.A254= | Silent (SNP) | VAF 14/392 reads (4%) | catalogued as COSV100904888; called by muse, mutect2
- MACC1 | c.1014C>T p.I338= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs535443647, COSV60540878; called by muse, mutect2, varscan2
- MAN2B1 | c.2391C>T p.R797= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs748899790, COSV55470144; called by muse, mutect2, varscan2
- NSMAF | c.804C>A p.I268= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as COSV50683877; called by muse, mutect2
- OR5M11 | c.573T>G p.T191= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV101602073, COSV73141966; called by muse, mutect2
- PLIN4 | c.525C>T p.A175= (on ENST00000301286; = p.A190= on NM_001367868.2) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs142527003; called by muse, mutect2, varscan2
- PNMA2 | c.759G>A p.R253= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV72908457; called by muse, mutect2, varscan2
- POU4F3 | c.873C>G p.A291= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV57942410; called by muse, mutect2, varscan2
- PTPRZ1 | c.2100A>C p.S700= | Silent (SNP) | VAF 24/245 reads (10%) | catalogued as COSV66430498; called by muse, mutect2, varscan2
- RYR2 | c.12678G>A p.P4226= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs768348987, COSV63663009; called by muse, mutect2, varscan2
- SCN5A | c.4458C>T p.F1486= (on ENST00000333535 / NM_198056.3; = p.F1485= on NM_000335.5) | Silent (SNP) | VAF 23/247 reads (9%) | catalogued as CD1010018, COSV61116151; called by muse, mutect2
- SMC5 | c.3276G>A p.R1092= | Silent (SNP) | VAF 148/324 reads (46%) | catalogued as COSV63191634; called by muse, mutect2, varscan2
- SNX4 | c.1080C>G p.T360= | Silent (SNP) | VAF 18/308 reads (6%) | catalogued as COSV99305331; called by muse, mutect2
- TSHZ2 | c.1434C>T p.V478= | Silent (SNP) | VAF 299/932 reads (32%) | catalogued as rs183008464, COSV61586886; called by muse, mutect2, varscan2
- WDR49 | c.270T>C p.D90= (on ENST00000308378 / NM_001366158.1; = p.D431= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 70/288 reads (24%) | catalogued as COSV57702440; called by muse, mutect2, varscan2
- ZKSCAN5 | c.645G>A p.V215= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as COSV100460421; called by muse, mutect2
- SYNE1 | c.23628-3798G>A | Intron (SNP) | VAF 60/130 reads (46%) | catalogued as rs541565377, COSV99582331; called by muse, mutect2, varscan2
- ZNF322P1 | n.89T>G | RNA (SNP) | VAF 20/516 reads (4%) | called by muse, mutect2
